Somatic mutation profile of tumor specimen TCGA-L9-A50W-01A (aliquot TCGA-L9-A50W-01A-12D-A397-08) from TCGA case TCGA-L9-A50W, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.1 years (27,414 days).
Specimen TCGA-L9-A50W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f7ab8bc-e2a2-4e20-b0c2-ab9cdc605f95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L9-A50W-10A (Blood Derived Normal), aliquot TCGA-L9-A50W-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e59b5718-84f4-48d1-9e79-c7e70b5b4a25

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Silent 4, Nonsense Mutation 3, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 56/100 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434569, CM054664, COSV51765492; ClinVar: drug response / likely pathogenic / pathogenic / protective; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 41/102 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AADAC | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99233271; called by muse, mutect2
- ADAM11 | c.980C>G p.T327S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99567515; called by muse, mutect2, varscan2
- ADAMTS3 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as rs199526921, COSV99710121; called by muse, mutect2, varscan2
- APC | c.1548+2T>G p.X516_splice | Splice Site (SNP) | VAF 31/64 reads (48%) | catalogued as COSV104378713, COSV99968103; called by muse, mutect2, varscan2
- CSMD3 | c.2249C>A p.T750K (on ENST00000297405 / NM_001363185.1; = p.T646K on NM_052900.3) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.837); catalogued as COSV52337134, COSV99820895; called by muse, mutect2, varscan2
- DISC1 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.311); catalogued as COSV99697881; called by muse, mutect2, varscan2
- ERC1 | c.2995C>T p.Q999* (on ENST00000360905 / NM_178040.4; = p.Q971* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100706136; called by muse, mutect2, varscan2
- EXOC8 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99149826; called by muse, mutect2, varscan2
- FRMPD4 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101043092; called by muse, mutect2, varscan2
- HNRNPM | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as rs1488519231, COSV100335216; called by muse, mutect2, varscan2
- KIF26B | c.4153A>C p.I1385L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1483768434, COSV100832583; called by muse, mutect2, varscan2
- LRRN1 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100076353; called by muse, mutect2
- MAP2K4 | c.331G>T p.G111* | Nonsense Mutation (SNP) | VAF 25/41 reads (61%) | catalogued as rs1418420168, COSV100796304, COSV100796548; called by muse, mutect2, varscan2
- NARF | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100559668; called by muse, mutect2, varscan2
- OR10J3 | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as COSV100171760; called by mutect2, varscan2
- POT1 | c.186T>A p.F62L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100714073; called by muse, mutect2, varscan2
- PTPRZ1 | c.4121T>C p.V1374A | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV101100192; called by muse, mutect2, varscan2
- RBM10 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 19/28 reads (68%) | catalogued as COSV61308202, COSV61312743; called by muse, mutect2, varscan2
- SCN1A | c.2418T>G p.V806= (on ENST00000303395 / NM_001202435.3; = p.V795= on NM_006920.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100320695; called by muse, mutect2, varscan2
- SLC20A1 | c.778+2T>C p.X260_splice | Splice Site (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99734094; called by muse, mutect2, varscan2
- SLC5A5 | c.1029C>A p.F343L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV99715103; called by muse, mutect2, varscan2
- SPG11 | c.3020T>G p.V1007G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV99968792; called by muse, mutect2, varscan2
- SPTB | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101072177; called by muse, mutect2, varscan2
- TMEM266 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV101189624; called by muse, mutect2, varscan2
- TTN | c.52649T>A p.F17550Y (on ENST00000591111; = p.F10126Y on NM_003319.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen possibly damaging (0.689); catalogued as COSV100616038; called by muse, mutect2
- UACA | c.1470A>T p.E490D | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.304); catalogued as COSV100537546; called by muse, mutect2, varscan2
- XYLT2 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV99190953; called by muse, mutect2, varscan2
- MYO5C | c.2268G>A p.L756= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99954836; called by muse, mutect2, varscan2
- PCNT | c.189C>T p.L63= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV52450898; called by muse, mutect2, varscan2
- SEC14L5 | c.1902C>T p.V634= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1455020302, COSV99228967; called by muse, mutect2, varscan2
- SEMA3G | c.363G>A p.R121= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
